Somatic mutation profile of tumor specimen HCM-CSHL-0835-C20-06A (aliquot HCM-CSHL-0835-C20-06A-11D-A85L-36) from HCMI case HCM-CSHL-0835-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.2 years (22,358 days).
Specimen HCM-CSHL-0835-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d1e567a-b591-4bfb-8543-7ac3dcbfcb47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0835-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0835-C20-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d810cf37-c315-4ae9-a359-bcc4e3465bd8

The open-access MAF lists 173 somatic variants for this specimen: 128 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 39, Frame Shift Del 9, Nonsense Mutation 7, Frame Shift Ins 6, Splice Region 3, Splice Site 2, 5'UTR 2, Intron 2, RNA 2, Translation Start Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 91/288 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AICDA | c.159C>T p.N53= | Splice Region (SNP) | VAF 84/203 reads (41%) | catalogued as COSV57565481; called by muse, mutect2, varscan2
- AL136295.1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs138817054; called by muse, mutect2, varscan2
- APC | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 110/272 reads (40%) | catalogued as COSV57323670, COSV57328904, COSV57399512; called by muse, mutect2, varscan2
- APLP1 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 82/254 reads (32%) | catalogued as rs372591248; called by muse, mutect2, varscan2
- ARHGEF33 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.105); catalogued as rs891432113, COSV67256660; called by muse, mutect2, varscan2
- ASB18 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1299574392; called by muse, mutect2, varscan2
- BPIFB4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 129/613 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs753941963, COSV64951254; called by muse, mutect2, varscan2
- CD1B | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.367); catalogued as rs757815693, COSV63804341; called by muse, mutect2, varscan2
- CDH12 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 206/315 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377660503; called by muse, mutect2, varscan2
- CLDN18 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs748597305; called by muse, mutect2, varscan2
- CPEB1 | c.34dup p.C12Lfs*9 | Frame Shift Ins (INS) | VAF 210/382 reads (55%) | catalogued as rs1271064291; called by mutect2, varscan2
- CRB1 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 64/301 reads (21%) | catalogued as COSV66345848; called by muse, mutect2, varscan2
- DGKQ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 177/443 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs147014854, COSV56616367; called by muse, mutect2, varscan2
- DPEP3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs181650862; called by muse, mutect2, varscan2
- DUSP26 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 161/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1315129621, COSV99823492; called by muse, mutect2, varscan2
- EML5 | c.3877G>A p.G1293S | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61341958; called by muse, mutect2, varscan2
- EZHIP | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 208/281 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1231114385; called by muse, mutect2, varscan2
- FAM126A | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 272/497 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs574238934; called by muse, mutect2, varscan2
- FAM180A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs890848627, COSV100647213; called by muse, mutect2, varscan2
- FAT3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as rs1444984775; called by muse, mutect2, varscan2
- FFAR1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs768739078; called by muse, mutect2, varscan2
- FREM2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 176/632 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs774024998; called by muse, mutect2, varscan2
- HERC2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 167/428 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs201542966, COSV55321457; called by muse, mutect2, varscan2
- IAPP | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs761079012, COSV53714105; called by muse, mutect2, varscan2
- INTS6 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778184413; called by muse, mutect2, varscan2
- IPMK | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.396); catalogued as rs139982255; called by muse, mutect2, varscan2
- KCNG1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 34/821 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1406953078; called by muse, mutect2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 138/396 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KDM5A | c.4261C>T p.R1421W | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1385893760; called by muse, mutect2, varscan2
- KIF2B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 167/376 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457562898, COSV52129186, COSV52132583, COSV52133299; called by muse, mutect2, varscan2
- KLF10 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 178/376 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1177113992; called by muse, mutect2, varscan2
- LIPI | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708335; called by muse, mutect2, varscan2
- LIPI | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143577177; called by muse, mutect2, varscan2
- MADD | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 157/401 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); catalogued as rs751993844, COSV60629198; called by muse, mutect2, varscan2
- MDGA2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 150/461 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs748391283, COSV67811984; called by muse, mutect2, varscan2
- NBEAL2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs745890949; called by muse, mutect2, varscan2
- NDST2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 138/337 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as rs757075560; called by muse, mutect2, varscan2
- NID1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 186/526 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV99938227; called by muse, mutect2, varscan2
- NLRP5 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV66763903; called by muse, mutect2, varscan2
- OR2L13 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63552199, COSV63552531; called by muse, mutect2, varscan2
- OR4C13 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.163); catalogued as rs1555015928; called by muse, mutect2, varscan2
- OSMR | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 100/482 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs370592814, COSV57086124; called by muse, mutect2, varscan2
- PCDHA13 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 172/492 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV56508960; called by muse, mutect2, varscan2
- PCDHB4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 255/642 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782064797, COSV52028091, COSV99521960; called by muse, mutect2, varscan2
- PHRF1 | c.2716C>T p.R906W (on ENST00000264555 / NM_001286581.2; = p.R905W on NM_020901.4) | Missense Mutation (SNP) | VAF 266/638 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1016832683, COSV52760435; called by muse, mutect2, varscan2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 397/732 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- PRDM9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 451/753 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs764241201, COSV57010337, COSV57015844; called by muse, mutect2, varscan2
- PRPF4B | c.190_192del p.D64del | In Frame Del (DEL) | VAF 28/174 reads (16%) | catalogued as rs1360981629; called by mutect2, pindel, varscan2
- PSG6 | c.458G>C p.S153T | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV51833396; called by muse, mutect2, varscan2
- RBMXL3 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 198/255 reads (78%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.98); catalogued as rs1032225014, COSV57757118; called by muse, mutect2, varscan2
- RGR | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs201335015, COSV100812996, COSV63893643; called by muse, mutect2, varscan2
- RP1L1 | c.4673C>T p.A1558V | Missense Mutation (SNP) | VAF 135/445 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs751542131; called by muse, mutect2, varscan2
- RTF1 | c.1206C>T p.V402= | Splice Region (SNP) | VAF 66/176 reads (38%) | catalogued as rs774225957; called by muse, mutect2, varscan2
- SCG2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 153/356 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as rs1163614408, COSV100544671, COSV59540102; called by muse, mutect2, varscan2
- SCN11A | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 139/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776182932, COSV56579054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 111/277 reads (40%) | catalogued as rs1281145992, COSV53435722, COSV99547827; called by muse, mutect2, varscan2
- SOHLH2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 127/447 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750638861, COSV65901195; called by muse, mutect2, varscan2
- TCF7L2 | c.468G>A p.W156* (on ENST00000355995 / NM_001367943.1; = p.W133* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 105/294 reads (36%) | catalogued as COSV100588727; called by muse, mutect2, varscan2
- TDRD15 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385396546, COSV68267170; called by muse, mutect2, varscan2
- TEX15 | c.5122dup p.R1708Kfs*6 (on ENST00000256246; = p.R2091Kfs*6 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 137/334 reads (41%) | catalogued as rs778104055; called by mutect2, varscan2
- TMEM71 | c.424C>A p.P142T (on ENST00000523829 / NM_001382398.1; = p.P123T on NM_144649.3) | Missense Mutation (SNP) | VAF 74/370 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.575); catalogued as COSV100785721; called by muse, mutect2, varscan2
- TNFSF14 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 171/443 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs200572645; called by muse, mutect2, varscan2
- TPO | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs750068617, COSV61094907; called by muse, varscan2
- USP8 | c.1990G>C p.G664R | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56163873; called by muse, mutect2, varscan2
- UTP14C | c.96T>A p.D32E | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs373793959; called by muse, mutect2, varscan2
- UTRN | c.6802C>T p.R2268* | Nonsense Mutation (SNP) | VAF 80/241 reads (33%) | catalogued as rs755543767, COSV100839969; called by muse, mutect2, varscan2
- XPO5 | c.651G>A p.A217= | Splice Region (SNP) | VAF 136/179 reads (76%) | catalogued as rs765845766, COSV54828311; called by muse, mutect2, varscan2
- YTHDF1 | c.773del p.G258Vfs*8 | Frame Shift Del (DEL) | VAF 173/685 reads (25%) | catalogued as rs1234547092, COSV64833859; called by mutect2, pindel, varscan2
- ZCCHC14 | c.1562C>T p.A521V (on ENST00000268616; = p.A658V on NM_015144.3) | Missense Mutation (SNP) | VAF 156/387 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as rs375771674; called by muse, mutect2, varscan2
- ZHX2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 180/560 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs759251479, COSV58714307; called by muse, mutect2, varscan2
- ALPP | c.1229A>C p.Y410S | Missense Mutation (SNP) | VAF 123/506 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATXN1 | c.1489A>T p.T497S | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 120/424 reads (28%) | called by pindel, varscan2
- C10orf71 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C8orf34 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 185/565 reads (33%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CCDC168 | c.16817A>G p.D5606G | Missense Mutation (SNP) | VAF 15/570 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.061); called by muse, mutect2
- CEP85L | c.1850A>T p.E617V | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2
- DNAH5 | c.3797A>T p.E1266V | Missense Mutation (SNP) | VAF 22/646 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- DYNC2I1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.794); called by muse, mutect2
- EGR4 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 131/519 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- EZH1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 68/171 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FNIP1 | c.1041del p.K347Nfs*17 | Frame Shift Del (DEL) | VAF 31/228 reads (14%) | called by mutect2, pindel, varscan2
- FOXE1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRB3 | c.806A>T p.Y269F | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GIMAP8 | c.1062del p.K354Nfs*6 | Frame Shift Del (DEL) | VAF 149/279 reads (53%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.797_800dup p.G268Rfs*22 (on ENST00000354667 / NM_031243.3; = p.G256Rfs*22 on NM_002137.4) | Frame Shift Ins (INS) | VAF 174/370 reads (47%) | called by mutect2, pindel, varscan2
- IBA57 | c.680-1G>A p.X227_splice | Splice Site (SNP) | VAF 78/232 reads (34%) | called by muse, mutect2, varscan2
- KCNF1 | c.1212del p.I405Sfs*25 | Frame Shift Del (DEL) | VAF 96/492 reads (20%) | called by mutect2, pindel, varscan2
- KIF5A | c.2933G>T p.S978I | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF5C | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- KIF5C | c.1149T>A p.S383R | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.434); called by muse, mutect2
- KLF10 | c.1391T>G p.V464G | Missense Mutation (SNP) | VAF 176/375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KLF8 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/156 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIMA1 | c.1405A>T p.N469Y | Missense Mutation (SNP) | VAF 137/352 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MAGI2 | c.1292dup p.S432Efs*16 | Frame Shift Ins (INS) | VAF 144/598 reads (24%) | called by mutect2, pindel, varscan2
- MAP1B | c.3814del p.L1272Wfs*6 | Frame Shift Del (DEL) | VAF 87/347 reads (25%) | called by mutect2, pindel, varscan2
- ME3 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSX1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 197/494 reads (40%) | called by muse, mutect2, varscan2
- MUC16 | c.22397C>A p.T7466K | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NADK | c.1199C>A p.T400N | Missense Mutation (SNP) | VAF 89/143 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NTNG1 | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 166/389 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR5J2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8H1 | c.298A>T p.M100L | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL6 | c.1278del p.L427Cfs*11 | Frame Shift Del (DEL) | VAF 74/243 reads (30%) | called by mutect2, pindel, varscan2
- PCDHA8 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- PCDHB12 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PEG3 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 155/416 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PLCH1 | c.155G>C p.R52P (on ENST00000340059 / NM_001130960.2; = p.R64P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PNMA3 | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 155/209 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POU2F2 | c.1025_1053delinsCAGA p.R342Pfs*47 (on ENST00000526816 / NM_001207025.3; = p.R326Pfs*47 on NM_002698.5) | Frame Shift Del (DEL) | VAF 100/456 reads (22%) | called by pindel, varscan2*
- RBM25 | c.2103A>T p.E701D | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RNF13 | c.821C>G p.T274S | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.304); called by muse, mutect2
- RYK | c.1734G>C p.M578I (on ENST00000620660 / NM_001005861.2; = p.M575I on NM_002958.4) | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SOX9 | c.1385dup p.Y463Lfs*115 | Frame Shift Ins (INS) | VAF 324/533 reads (61%) | called by mutect2, pindel, varscan2
- TEX44 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 145/353 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGM4 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLE1 | c.2128+1G>C p.X710_splice | Splice Site (SNP) | VAF 23/174 reads (13%) | called by muse, varscan2
- TMEM237 | c.637A>G p.T213A (on ENST00000409883 / NM_001044385.3; = p.T205A on NM_152388.4) | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TMEM71 | c.425C>T p.P142L (on ENST00000523829 / NM_001382398.1; = p.P123L on NM_144649.3) | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TOMM20 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- TRPC4 | c.2747C>A p.T916K (on ENST00000379705 / NM_016179.4; = p.T921K on NM_003306.3) | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM3 | c.2309G>T p.R770L (on ENST00000357533 / NM_001366142.2; = p.R613L on NM_020952.6) | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPV2 | c.1200del p.Y401Tfs*15 | Frame Shift Del (DEL) | VAF 32/321 reads (10%) | called by mutect2, pindel, varscan2
- UBE3A | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP8 | c.1559_1560dup p.A521Kfs*29 | Frame Shift Ins (INS) | VAF 73/252 reads (29%) | called by mutect2, pindel, varscan2
- ZBBX | c.1866G>T p.R622S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF831 | c.4069T>C p.S1357P | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ABRA | c.1099C>T p.L367= | Silent (SNP) | VAF 78/367 reads (21%) | called by muse, mutect2, varscan2
- AKAP12 | c.1083G>A p.P361= | Silent (SNP) | VAF 65/397 reads (16%) | catalogued as rs1283030412, COSV53573988, COSV99483535; called by muse, mutect2, varscan2
- ALB | c.1038A>C p.A346= | Silent (SNP) | VAF 25/293 reads (9%) | called by muse, mutect2
- ARHGEF19 | c.1992C>T p.P664= | Silent (SNP) | VAF 157/258 reads (61%) | catalogued as rs151051853, COSV99580312; called by muse, mutect2, varscan2
- C10orf71 | c.4113C>T p.R1371= | Silent (SNP) | VAF 198/472 reads (42%) | catalogued as rs1242522499, COSV60506696; called by muse, mutect2, varscan2
- CCDC136 | c.3426G>A p.S1142= | Silent (SNP) | VAF 228/416 reads (55%) | catalogued as COSV52802604; called by muse, mutect2, varscan2
- CFTR | c.2835G>A p.S945= | Silent (SNP) | VAF 117/380 reads (31%) | catalogued as rs193922513, COSV50081176; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- DAAM2 | c.1479G>A p.E493= | Silent (SNP) | VAF 89/351 reads (25%) | catalogued as COSV51420434; called by muse, mutect2, varscan2
- DPYSL3 | c.894G>A p.A298= | Silent (SNP) | VAF 135/331 reads (41%) | catalogued as rs200777055, COSV58331098; called by muse, mutect2, varscan2
- EIF4G1 | c.3531G>A p.A1177= (on ENST00000346169 / NM_198241.3; = p.A982= on NM_004953.5) | Silent (SNP) | VAF 129/381 reads (34%) | catalogued as rs763154760, COSV59991267; called by muse, mutect2, varscan2
- EXOC4 | c.2790C>T p.T930= | Silent (SNP) | VAF 13/438 reads (3%) | called by muse, mutect2
- FAT4 | c.300C>T p.S100= | Silent (SNP) | VAF 183/431 reads (42%) | called by muse, mutect2, varscan2
- FLT3 | c.579C>T p.I193= | Silent (SNP) | VAF 109/395 reads (28%) | catalogued as rs775998708; called by muse, mutect2, varscan2
- GABPA | c.558C>T p.P186= | Silent (SNP) | VAF 60/177 reads (34%) | called by muse, mutect2, varscan2
- GABRE | c.306C>T p.S102= | Silent (SNP) | VAF 125/161 reads (78%) | catalogued as rs375575457; called by muse, mutect2, varscan2
- GPR87 | c.939T>C p.I313= | Silent (SNP) | VAF 104/304 reads (34%) | called by muse, mutect2, varscan2
- IGLV2-14 | c.81C>T p.A27= | Silent (SNP) | VAF 174/457 reads (38%) | catalogued as rs552858399; called by muse, mutect2, varscan2
- INHBA | c.258G>A p.A86= | Silent (SNP) | VAF 152/560 reads (27%) | catalogued as rs780556409, COSV54219416, COSV54225307, COSV54225743; called by muse, mutect2, varscan2
- INTS6 | c.1827A>T p.P609= | Silent (SNP) | VAF 107/407 reads (26%) | called by muse, mutect2, varscan2
- KAT14 | c.1407G>A p.K469= | Silent (SNP) | VAF 271/469 reads (58%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.75G>A p.S25= | Silent (SNP) | VAF 104/325 reads (32%) | catalogued as rs1267777001, COSV55430587; called by muse, mutect2, varscan2
- KLHL1 | c.2199G>A p.L733= | Silent (SNP) | VAF 75/328 reads (23%) | catalogued as COSV64770258; called by muse, mutect2, varscan2
- LAP3 | c.42C>G p.V14= | Silent (SNP) | VAF 133/368 reads (36%) | called by muse, mutect2, varscan2
- LMTK3 | c.3984G>C p.G1328= | Silent (SNP) | VAF 207/528 reads (39%) | called by muse, mutect2, varscan2
- NFATC1 | c.1083G>A p.P361= | Silent (SNP) | VAF 153/277 reads (55%) | catalogued as rs370647787; called by muse, mutect2, varscan2
- NRXN1 | c.3189G>A p.P1063= | Silent (SNP) | VAF 30/362 reads (8%) | catalogued as rs141566634; ClinVar: uncertain significance; called by muse, mutect2
- P2RX2 | c.30C>T p.A10= | Silent (SNP) | VAF 86/362 reads (24%) | catalogued as rs749843274; called by muse, mutect2, varscan2
- PRDM6 | c.537C>A p.G179= | Silent (SNP) | VAF 147/381 reads (39%) | called by muse, mutect2, varscan2
- PXDN | c.2688C>T p.S896= | Silent (SNP) | VAF 137/350 reads (39%) | catalogued as rs747948602, COSV53240194; called by muse, mutect2, varscan2
- RIOK3 | c.588A>G p.L196= | Silent (SNP) | VAF 97/155 reads (63%) | called by muse, mutect2, varscan2
- SLC12A3 | c.2898C>T p.Y966= (on ENST00000563236 / NM_001126108.2; = p.Y975= on NM_000339.3) | Silent (SNP) | VAF 96/206 reads (47%) | called by muse, varscan2
- SMARCA2 | c.1017C>T p.P339= | Silent (SNP) | VAF 113/262 reads (43%) | catalogued as rs750120946, COSV61804287; called by muse, mutect2, varscan2
- SON | c.2037A>C p.T679= | Silent (SNP) | VAF 116/307 reads (38%) | called by muse, mutect2, varscan2
- SPTB | c.1785C>T p.T595= | Silent (SNP) | VAF 93/242 reads (38%) | catalogued as rs552724363, COSV67630278; called by muse, mutect2, varscan2
- TCP11L1 | c.1266C>T p.T422= | Silent (SNP) | VAF 139/375 reads (37%) | catalogued as rs756467493, COSV57514872; called by muse, mutect2, varscan2
- TNXB | c.5157G>A p.P1719= (on ENST00000647633; = p.P1472= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 255/326 reads (78%) | catalogued as rs777358881; called by muse, mutect2, varscan2
- WSCD1 | c.1101A>G p.A367= | Silent (SNP) | VAF 77/285 reads (27%) | called by muse, mutect2, varscan2
- ZNF469 | c.9003C>T p.D3001= (on ENST00000437464; = p.D3029= on NM_001367624.2) | Silent (SNP) | VAF 190/513 reads (37%) | catalogued as rs780843955, COSV71258309; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNRF2 | c.615A>G p.E205= | Silent (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- ANTXR1 | c.-71G>A | 5'UTR (SNP) | VAF 125/458 reads (27%) | catalogued as COSV58009244; called by muse, mutect2, varscan2
- CCL7 | c.77-12G>T | Intron (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- CD300LB | c.-27C>T | 5'UTR (SNP) | VAF 25/249 reads (10%) | catalogued as rs376945758; called by muse, mutect2, varscan2
- MASP1 | c.1303+5315G>A | Intron (SNP) | VAF 197/451 reads (44%) | catalogued as rs765087753; called by muse, mutect2, varscan2
- MIR100HG | n.244G>T | RNA (SNP) | VAF 121/282 reads (43%) | called by muse, mutect2, varscan2
- SLC22A17 | n.271G>A | RNA (SNP) | VAF 170/587 reads (29%) | called by muse, mutect2, varscan2
